Somatic mutation profile of tumor specimen HCM-WCMC-1284-C67-01B (aliquot HCM-WCMC-1284-C67-01B-01D-A905-36) from HCMI case HCM-WCMC-1284-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-1284-C67-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d67c1bda-b87f-4918-8bfd-58ea4ce450a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1284-C67-11A (Slides), aliquot HCM-WCMC-1284-C67-11A-15D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62cb8edc-f34a-41a3-9fdb-06c95dd53cc2

The open-access MAF lists 183 somatic variants for this specimen: 137 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 39, Nonsense Mutation 15, Intron 4, Splice Region 2, Splice Site 1, 3'UTR 1, In Frame Del 1, RNA 1, 5'UTR 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHEK2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 161/359 reads (45%) | catalogued as rs587781269, CM110734, COSV60421481; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 117/176 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 62/364 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553488015, COSV67960750, COSV67961406; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 162/375 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1273238867; called by muse, mutect2, varscan2
- AIMP2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 196/425 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV56151895, COSV56151903; called by muse, mutect2, varscan2
- AP4E1 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55916742, COSV99956145; called by muse, mutect2, varscan2
- ARID1B | c.4651G>T p.E1551* | Nonsense Mutation (SNP) | VAF 196/418 reads (47%) | catalogued as rs1554235925, COSV51678781; called by muse, mutect2, varscan2
- BRINP2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 27/475 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.203); catalogued as rs377625274, COSV64179611; called by muse, mutect2
- C17orf97 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 80/173 reads (46%) | catalogued as rs1304810206; called by muse, mutect2, varscan2
- C19orf57 | c.1053G>C p.E351D | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs983428153; called by muse, mutect2, varscan2
- C7orf61 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 154/361 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1417789451; called by muse, mutect2, varscan2
- CFAP20 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 178/453 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as rs764778355; called by muse, mutect2, varscan2
- DEFB112 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 169/423 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs146242544; called by muse, mutect2, varscan2
- DNAH2 | c.12492G>C p.K4164N | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV66716154; called by muse, mutect2, varscan2
- EFCAB12 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 188/435 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV100394474; called by muse, mutect2, varscan2
- EFCAB6 | c.4438G>T p.E1480* | Nonsense Mutation (SNP) | VAF 130/274 reads (47%) | catalogued as COSV53063018; called by muse, mutect2, varscan2
- EIF4A1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs199974690, COSV53441875; called by muse, mutect2, varscan2
- EP300 | c.1604C>A p.S535* | Nonsense Mutation (SNP) | VAF 113/271 reads (42%) | catalogued as COSV54341353; called by muse, mutect2, varscan2
- ETV4 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.989); catalogued as rs1426178575; called by muse, mutect2, varscan2
- FAM153A | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 205/430 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV62363563; called by muse, mutect2, varscan2
- FGD5 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 119/325 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768184216; called by muse, mutect2, varscan2
- FHOD3 | c.4184C>G p.S1395C (on ENST00000359247 / NM_001281739.3; = p.S1412C on NM_025135.5) | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57185201; called by muse, mutect2, varscan2
- GCOM1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as COSV51093995, COSV51096943; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 230/510 reads (45%) | SIFT tolerated (0.07); catalogued as rs760519128; called by muse, varscan2
- GRIP1 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 147/386 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54030917; called by muse, mutect2, varscan2
- HDAC1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV61482263; called by muse, mutect2, varscan2
- HELZ2 | c.7606C>T p.R2536W (on ENST00000467148 / NM_001037335.2; = p.R1967W on NM_033405.3) | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs369824932; called by muse, mutect2, varscan2
- HERC2 | c.4823C>T p.P1608L | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs781394266; called by muse, mutect2, varscan2
- ITPR1 | c.5287G>A p.G1763S (on ENST00000354582; = p.G1708S on NM_002222.7) | Missense Mutation (SNP) | VAF 226/530 reads (43%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.874); catalogued as COSV100231673; called by muse, mutect2, varscan2
- KIF26B | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1464469598; called by muse, mutect2, varscan2
- KIF2C | c.760-1G>A p.X254_splice | Splice Site (SNP) | VAF 106/319 reads (33%) | catalogued as COSV100945886; called by muse, mutect2, varscan2
- KMT2C | c.13750C>T p.R4584W | Missense Mutation (SNP) | VAF 202/450 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747850540, COSV51428250; called by muse, mutect2, varscan2
- L1TD1 | c.1439A>T p.E480V | Missense Mutation (SNP) | VAF 151/318 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs373045440; called by muse, mutect2, varscan2
- LAT2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 40/239 reads (17%) | catalogued as COSV51920379; called by muse, mutect2, varscan2
- MAPK15 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 123/265 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs782408799; called by muse, varscan2
- MIER2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 117/230 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53398974; called by muse, mutect2, varscan2
- MKI67 | c.6832G>C p.D2278H | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV64075443; called by muse, varscan2
- MXRA5 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs144916947; called by muse, mutect2, varscan2
- NACC1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 130/299 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99456836; called by muse, mutect2, varscan2
- NAP1L5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 187/539 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.602); catalogued as rs1253186333; called by muse, varscan2
- NELL1 | c.2324G>C p.R775P | Missense Mutation (SNP) | VAF 215/473 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100122487, COSV54263969, COSV54298710; called by muse, mutect2, varscan2
- OR6K3 | c.183C>G p.I61M (on ENST00000368146; = p.I45M on NM_001005327.2) | Missense Mutation (SNP) | VAF 162/368 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV63746116; called by muse, mutect2, varscan2
- PCDHB9 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 27/680 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as rs569944736; called by muse, mutect2
- PRPF38B | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 182/410 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64223491; called by muse, varscan2
- PTPRD | c.5611G>A p.D1871N | Missense Mutation (SNP) | VAF 55/442 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61933475, COSV61958476; called by muse, mutect2, varscan2
- ROR2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 196/451 reads (43%) | catalogued as rs943841260; called by muse, mutect2, varscan2
- RPH3A | c.221A>G p.E74G (on ENST00000389385 / NM_001143854.2; = p.E70G on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs540323896; called by muse, mutect2, varscan2
- RYR1 | c.7614G>A p.T2538= | Splice Region (SNP) | VAF 76/156 reads (49%) | catalogued as rs1207360336, COSV62105906; called by muse, mutect2
- SCARA3 | c.1673C>G p.S558* | Nonsense Mutation (SNP) | VAF 121/294 reads (41%) | catalogued as COSV57271786; called by muse, mutect2, varscan2
- SLC25A3 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1044154623; called by muse, mutect2, varscan2
- TP63 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM0910987, CS095574, COSV53197664; called by muse, mutect2, varscan2
- UGT2B10 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 138/374 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs773034258; called by muse, mutect2, varscan2
- UNC13C | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 140/353 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs749619544, COSV99515933; called by muse, mutect2, varscan2
- WIPF1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV55815670; called by muse, mutect2, varscan2
- ZNF516 | c.3253C>T p.H1085Y | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs1166542823; called by muse, mutect2
- AC097637.1 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS8 | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRV1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ALK | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ALS2 | c.3652G>T p.D1218Y | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKIB1 | c.1620C>T p.C540= | Splice Region (SNP) | VAF 103/222 reads (46%) | called by muse, mutect2, varscan2
- APBB3 | c.1201G>C p.E401Q (on ENST00000357560 / NM_133173.2; = p.E408Q on NM_006051.3) | Missense Mutation (SNP) | VAF 125/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF10 | c.2611C>G p.H871D (on ENST00000398564; = p.H846D on NM_014629.4) | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C12orf29 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 174/428 reads (41%) | called by muse, varscan2
- CALM3 | c.449G>C p.*150Sext*37 | Nonstop Mutation (SNP) | VAF 64/354 reads (18%) | called by muse, mutect2, varscan2
- CCDC102A | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCDC88B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNT2 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 144/303 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNGB1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 228/536 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNOT3 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- COX16 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 134/358 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSTF1 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DAAM1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 188/457 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DDX60L | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 204/365 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- DHFR | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EPPK1 | c.4842C>G p.I1614M | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- FAM186A | c.4483C>G p.L1495V | Missense Mutation (SNP) | VAF 124/422 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, varscan2
- FAM214A | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 229/534 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- FAM71E2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 73/191 reads (38%) | called by muse, varscan2
- FANCB | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 221/247 reads (89%) | called by muse, mutect2, varscan2
- FAT4 | c.11678G>T p.G3893V | Missense Mutation (SNP) | VAF 135/483 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRYL | c.8434G>A p.D2812N | Missense Mutation (SNP) | VAF 102/413 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GARRE1 | c.1345C>G p.Q449E | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GLIPR2 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- GOLGA4 | c.3606G>C p.K1202N | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GOLGA4 | c.4440G>C p.Q1480H | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- GRIN3B | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.055); called by muse, varscan2
- HDAC1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- HEATR9 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 198/440 reads (45%) | called by muse, varscan2
- JMJD1C | c.6783G>C p.L2261F | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM7A | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF20A | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 19/489 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2
- KMT2D | c.15611_15623del p.A5204Gfs*35 | Frame Shift Del (DEL) | VAF 104/301 reads (35%) | called by mutect2, varscan2
- KMT2D | c.10495C>T p.Q3499* | Nonsense Mutation (SNP) | VAF 141/321 reads (44%) | called by muse, mutect2, varscan2
- MAP3K2 | c.1517A>G p.K506R | Missense Mutation (SNP) | VAF 248/570 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MEFV | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MKI67 | c.6722G>C p.R2241T | Missense Mutation (SNP) | VAF 137/244 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, varscan2
- MTMR12 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS1 | c.2635A>G p.R879G (on ENST00000262102 / NM_001363061.1; = p.R45G on NM_020749.4) | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2
- MUC16 | c.25715C>G p.S8572* | Nonsense Mutation (SNP) | VAF 172/375 reads (46%) | called by muse, mutect2, varscan2
- MVK | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 198/428 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAPB | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NKIRAS2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NUP155 | c.2067G>C p.K689N (on ENST00000231498 / NM_153485.3; = p.K630N on NM_004298.4) | Missense Mutation (SNP) | VAF 161/365 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.12742C>G p.P4248A | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OSBPL5 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 164/329 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- POU1F1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 188/477 reads (39%) | called by muse, mutect2, varscan2
- PPP5C | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- RAD54L2 | c.3169C>A p.P1057T | Missense Mutation (SNP) | VAF 71/416 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RBM42 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- RIF1 | c.6340_6345del p.H2114_H2115del | In Frame Del (DEL) | VAF 97/286 reads (34%) | called by mutect2, varscan2
- RMDN1 | c.845G>C p.W282S | Missense Mutation (SNP) | VAF 238/508 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- RNFT1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPE65 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL23 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RTL3 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RUFY3 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SEC61B | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SHMT1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX17 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 139/299 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- STOX1 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 155/282 reads (55%) | called by muse, mutect2, varscan2
- TAF1A | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 133/326 reads (41%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TAF7 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TDRD15 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TGM5 | c.859A>T p.T287S (on ENST00000220420 / NM_201631.4; = p.T205S on NM_004245.4) | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TOPAZ1 | c.3175G>C p.G1059R | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRMT1L | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TUBB8 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR54 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 145/367 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- YBEY | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ZAN | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE9 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- ZMYND19 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 165/321 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF148 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 185/437 reads (42%) | called by muse, mutect2, varscan2
- ZNF497 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 112/215 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZNF808 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ABCA5 | c.198C>G p.L66= | Silent (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2
- ABCB11 | c.3456C>G p.L1152= | Silent (SNP) | VAF 84/531 reads (16%) | called by muse, mutect2, varscan2
- ADGRA3 | c.459C>T p.T153= | Silent (SNP) | VAF 207/341 reads (61%) | catalogued as rs760105617; called by muse, mutect2, varscan2
- ANKS1B | c.1323T>G p.A441= | Silent (SNP) | VAF 26/453 reads (6%) | called by muse, mutect2
- CACNA1A | c.4422C>T p.D1474= | Silent (SNP) | VAF 102/240 reads (43%) | catalogued as rs374555263; ClinVar: likely benign; called by muse, varscan2
- CASKIN1 | c.2571G>A p.P857= | Silent (SNP) | VAF 96/189 reads (51%) | catalogued as rs759731785, COSV58212568; called by muse, mutect2, varscan2
- CLSTN2 | c.252G>A p.K84= | Silent (SNP) | VAF 141/298 reads (47%) | catalogued as COSV101515613; called by muse, mutect2, varscan2
- CRACD | c.2310G>A p.G770= | Silent (SNP) | VAF 101/364 reads (28%) | catalogued as rs746345219, COSV99948928; called by muse, mutect2, varscan2
- DGKD | c.1962G>A p.K654= (on ENST00000264057 / NM_152879.3; = p.K610= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 154/331 reads (47%) | called by muse, mutect2, varscan2
- EFR3B | c.2388C>T p.Y796= | Silent (SNP) | VAF 200/409 reads (49%) | catalogued as rs1177829793; called by muse, mutect2, varscan2
- ENTPD3 | c.384C>T p.L128= | Silent (SNP) | VAF 86/512 reads (17%) | called by muse, mutect2, varscan2
- FAM71E2 | c.324C>T p.L108= | Silent (SNP) | VAF 85/182 reads (47%) | catalogued as rs961471384; called by muse, mutect2, varscan2
- GLUD2 | c.1176C>T p.N392= | Silent (SNP) | VAF 37/314 reads (12%) | catalogued as rs1242855174, COSV60151317; called by muse, mutect2, varscan2
- HDAC4 | c.477G>A p.E159= | Silent (SNP) | VAF 145/292 reads (50%) | called by muse, mutect2, varscan2
- HEATR9 | c.1059C>G p.L353= | Silent (SNP) | VAF 208/465 reads (45%) | called by muse, mutect2, varscan2
- HS3ST4 | c.603C>T p.L201= | Silent (SNP) | VAF 55/274 reads (20%) | catalogued as rs1452322190; called by muse, mutect2, varscan2
- IGSF9 | c.2109C>T p.F703= (on ENST00000368094 / NM_001135050.2; = p.F687= on NM_020789.4) | Silent (SNP) | VAF 63/338 reads (19%) | catalogued as rs776748563, COSV63641758; called by muse, mutect2, varscan2
- ITFG2 | c.633G>A p.L211= | Silent (SNP) | VAF 144/333 reads (43%) | catalogued as rs981684476; called by muse, mutect2, varscan2
- KCNH5 | c.2130C>T p.F710= | Silent (SNP) | VAF 237/501 reads (47%) | catalogued as rs1208483577; called by muse, mutect2, varscan2
- KCNV2 | c.990C>T p.F330= | Silent (SNP) | VAF 203/221 reads (92%) | catalogued as rs773388753, COSV66057256, COSV66058001; called by muse, mutect2, varscan2
- KRTAP19-7 | c.54C>T p.F18= | Silent (SNP) | VAF 212/458 reads (46%) | catalogued as rs572700402, COSV58366022, COSV58366262; called by muse, mutect2, varscan2
- LHPP | c.495G>A p.L165= | Silent (SNP) | VAF 80/262 reads (31%) | called by muse, mutect2
- MED12L | c.549G>A p.P183= | Silent (SNP) | VAF 92/235 reads (39%) | catalogued as rs148202747; called by muse, mutect2, varscan2
- MED13 | c.5169G>C p.R1723= | Silent (SNP) | VAF 201/469 reads (43%) | called by muse, mutect2, varscan2
- MEX3C | c.144G>A p.L48= | Silent (SNP) | VAF 76/168 reads (45%) | called by muse, mutect2, varscan2
- NBPF3 | c.795C>T p.I265= | Silent (SNP) | VAF 19/430 reads (4%) | catalogued as COSV59056346; called by muse, mutect2
- POU1F1 | c.759G>T p.L253= | Silent (SNP) | VAF 188/481 reads (39%) | catalogued as COSV99773269; called by muse, mutect2, varscan2
- PRTN3 | c.390C>T p.L130= | Silent (SNP) | VAF 79/174 reads (45%) | called by muse, mutect2, varscan2
- PTPN13 | c.7401C>G p.V2467= (on ENST00000411767 / NM_080683.3; = p.V2448= on NM_006264.3) | Silent (SNP) | VAF 131/410 reads (32%) | called by muse, mutect2, varscan2
- RAB27A | c.267C>T p.F89= | Silent (SNP) | VAF 107/267 reads (40%) | called by muse, mutect2, varscan2
- RTL1 | c.2367G>C p.L789= | Silent (SNP) | VAF 50/268 reads (19%) | called by muse, mutect2, varscan2
- RTTN | c.108C>T p.Y36= | Silent (SNP) | VAF 242/544 reads (44%) | catalogued as COSV55341424; called by muse, mutect2, varscan2
- SLC12A5 | c.15C>T p.F5= | Silent (SNP) | VAF 70/167 reads (42%) | called by muse, mutect2, varscan2
- SLC17A9 | c.165C>T p.F55= | Silent (SNP) | VAF 121/302 reads (40%) | catalogued as rs1204167432, COSV64847072; called by muse, mutect2, varscan2
- SLC38A3 | c.1467C>T p.I489= | Silent (SNP) | VAF 105/240 reads (44%) | catalogued as rs1275943011; called by muse, varscan2
- TEDC2 | c.21G>C p.S7= | Silent (SNP) | VAF 67/169 reads (40%) | called by muse, mutect2, varscan2
- TPM2 | c.558C>T p.A186= | Silent (SNP) | VAF 111/233 reads (48%) | catalogued as rs746177794; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- VEZF1 | c.813C>T p.A271= | Silent (SNP) | VAF 159/424 reads (38%) | called by muse, mutect2, varscan2
- YIPF4 | c.288G>A p.L96= | Silent (SNP) | VAF 147/356 reads (41%) | catalogued as COSV53212923; called by muse, varscan2
- AL121718.1 | n.316C>A | RNA (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- CDH13 | c.157+34C>T | Intron (SNP) | VAF 162/399 reads (41%) | called by muse, mutect2, varscan2
- DPP6 | c.244-140695G>A | Intron (SNP) | VAF 62/298 reads (21%) | catalogued as rs1401432607, COSV100126800, COSV59620421; called by muse, varscan2
- MACF1 | c.15832-10632G>A | Intron (SNP) | VAF 214/471 reads (45%) | called by muse, mutect2, varscan2
- MYOG | c.*147C>A | 3'UTR (SNP) | VAF 132/297 reads (44%) | called by muse, mutect2, varscan2
- PRR12 | c.52-615G>C | Intron (SNP) | VAF 47/245 reads (19%) | called by muse, mutect2, varscan2
- VPS11 | c.-960G>C | 5'UTR (SNP) | VAF 111/286 reads (39%) | called by muse, mutect2, varscan2
